Gene-level copy-number profile of tumor specimen TCGA-06-2561-01A from TCGA case TCGA-06-2561, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,505 days).
Specimen TCGA-06-2561-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b5c4a773-58f3-40b3-bb09-0a5dfa5560e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-2561-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9956be45-ac1a-4e41-a27d-b4c1f750556d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 13,284; copy number 2: 40,431; copy number 3: 5,759; copy number 4: 57; copy number 6: 248; copy number 7: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-2561-01A-02D-0784-01): tumor purity 0.46, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:22,646,200–23,438,700, 5 genes: LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr9:25,676,389–25,678,440, 1 gene: TUSC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 269 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:243,124,428–243,255,348, 1 gene, copy number 7 (within-gene range 2–7): CEP170.
- chr1:243,256,034–244,451,909, 20 genes, copy number 7: SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2.
- chr12:20,695,332–33,576,200, 248 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,284. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
